Somatic mutation profile of tumor specimen TCGA-DJ-A2Q7-01A (aliquot TCGA-DJ-A2Q7-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2Q7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 52.5 years (19,193 days).
Specimen TCGA-DJ-A2Q7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69842526-d2bc-44c6-88c4-bda47d9d9424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2Q7-10A (Blood Derived Normal), aliquot TCGA-DJ-A2Q7-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d87374aa-6598-4d9b-82b1-3299e32a9fa6

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FCGR2B | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52681119; called by muse, mutect2, varscan2
- FRMPD3 | c.3212C>T p.T1071I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV52188513; called by muse, mutect2, varscan2
- MAP1B | c.5981C>T p.S1994F | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as COSV57096450; called by muse, mutect2
- FUT9 | c.609C>G p.V203= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs989822927, COSV56144385; called by muse, mutect2, varscan2
- MEF2C | c.450C>G p.S150= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV60928074; called by muse, mutect2, varscan2
- MLLT1 | c.1599C>T p.T533= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as COSV53129819; called by muse, mutect2, varscan2
- MYH8 | c.5475T>A p.L1825= | Silent (SNP) | VAF 7/187 reads (4%) | catalogued as COSV101238587, COSV67962357; called by muse, mutect2
- ST18 | c.231G>A p.R77= | Silent (SNP) | VAF 40/235 reads (17%) | catalogued as COSV52489158; called by muse, mutect2, varscan2
- ZBTB26 | c.423A>G p.P141= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV65402991; called by muse, mutect2, varscan2
